Gene-level copy-number profile of specimen HCM-CSHL-0584-C19-85M from HCMI case HCM-CSHL-0584-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 58.7 years (21,437 days).
Specimen HCM-CSHL-0584-C19-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a0625bb9-1e9b-4360-9425-a78d5069dd63.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0584-C19-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,255 have no estimate.
https://portal.gdc.cancer.gov/files/9aad88f0-07eb-4690-a8bd-8d01c50fab20

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 5; copy number 2: 6,185; copy number 3: 623; copy number 4: 32,287; copy number 5: 3,159; copy number 6: 11,118; copy number 7: 2,466; copy number 8: 1,395; copy number 9: 277; copy number 10: 695; copy number 11: 3; copy number 12: 106; copy number 13: 21; copy number 44: 28.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,130 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,450,245, 3 genes, copy number 12: AC239859.5, RNA5SP533, AC239859.3.
- chr2:86,907,953–87,013,976, 1 gene, copy number 9 (within-gene range 6–9): RGPD1.
- chr2:87,002,559–87,021,852, 1 gene, copy number 9: PLGLB1.
- chr8:38,400,215–38,468,834, 1 gene, copy number 10 (within-gene range 7–10): FGFR1.
- chr8:38,421,889–38,601,200, 5 genes, copy number 9–12: AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1.
- chr8:47,089,572–47,960,178, 20 genes, copy number 9: AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA, AC021236.1.
- chr9:40,346,144–40,347,052, 1 gene, copy number 9: CNN2P2.
- chr13:68,861,284–73,227,260, 39 genes, copy number 9: LINC00550, LINC02342, ZDHHC20P4, SNRPFP3, LINC00383, SRSF1P1, KLHL1, RNY3P10, PSMC1P13, ATXN8OS, AL160391.1, RNU6-54P, AL445264.1, MTCL1P1, LINC00348, RABEPKP1, DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21, AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8.
- chr13:73,413,473–78,617,328, 64 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr14:22,155,079–22,190,713, 6 genes, copy number 9: TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33.
- chr15:53,513,741–56,629,592, 44 genes, copy number 10: WDR72, RNU2-53P, RNU6-449P, AC084759.1, AC084759.3, AC084759.2, UNC13C, AC010867.1, HNRNPA1P74, AC025272.1, AC011912.1, RSL24D1, RAB27A, AC018926.2, PIGBOS1, PIGB, CCPG1, AC018926.1, AC018926.3, DNAAF4-CCPG1, MIR628, C15orf65, DNAAF4, AC013355.1, PYGO1, AC012378.2, PRTG, AC012378.1, AC009997.1, NEDD4, CNOT6LP1, RN7SL568P, CD24P2, RFX7, AC084783.1, TEX9, AC068726.1, RNU6-1287P, HMGB1P33, AC084782.1, AC084782.2, MNS1, AC084782.3, AC090518.1.
- chr15:88,898,683–94,550,572, 164 genes, copy number 9–13 (broad region; genes not listed).
- chr16:28,499,362–30,523,567, 154 genes, copy number 10–13 (broad region; genes not listed).
- chr19:4,292,232–4,323,843, 2 genes, copy number 9: TMIGD2, FSD1.
- chr19:4,402,640–4,502,208, 9 genes, copy number 10 (within-gene range 7–10): CHAF1A, AC011498.3, UBXN6, MIR4746, AC011498.2, AC011498.7, AC011498.6, AC011498.1, HDGFL2.
- chr19:29,001,670–29,015,160, 2 genes, copy number 9: RNA5SP470, LINC01532.
- chr20:31,377,164–31,944,963, 27 genes, copy number 10 (within-gene range 8–10): DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P.
- chr20:34,194,569–59,516,039, 587 genes, copy number 10–44 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
